Somatic mutation profile of tumor specimen TCGA-55-7903-01A (aliquot TCGA-55-7903-01A-11D-2167-08) from TCGA case TCGA-55-7903, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.4 years (23,509 days).
Specimen TCGA-55-7903-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97cf780a-4074-4cbe-ba26-46ee2e6fbbe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7903-10A (Blood Derived Normal), aliquot TCGA-55-7903-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b20b84a2-0052-435c-ac00-74300e76519d

The open-access MAF lists 168 somatic variants for this specimen: 132 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 33, Frame Shift Del 9, Nonsense Mutation 4, Intron 3, Splice Region 3, Splice Site 2, In Frame Del 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRG6 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764999436, COSV51596634; called by muse, mutect2, varscan2
- ADGRG7 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV56299038; called by muse, mutect2, varscan2
- AFP | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV56926159; called by muse, mutect2, varscan2
- AP3B1 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54888175, COSV99670591; called by muse, mutect2, varscan2
- ARL2BP | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV54656409; called by muse, mutect2, varscan2
- ARSB | c.728A>G p.E243G | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53726701; called by muse, mutect2, varscan2
- ASNS | c.1649G>T p.R550L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51554162; called by muse, mutect2, varscan2
- BRAF | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs769648920, COSV56273855; called by muse, mutect2, varscan2
- C9 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 49/178 reads (28%) | catalogued as rs144138616, CM970207; called by muse, mutect2, varscan2
- CACNA1C | c.1891A>T p.T631S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59745357; called by muse, mutect2, varscan2
- CACNA2D1 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV62385745; called by muse, mutect2, varscan2
- CAMK1D | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV66615905; called by muse, mutect2, varscan2
- CASZ1 | c.4111A>T p.M1371L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.098); catalogued as COSV59738643; called by muse, mutect2, varscan2
- CDH9 | c.1891G>A p.V631M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV50344969; called by muse, mutect2, varscan2
- CHD9 | c.1947A>G p.I649M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV68299204; called by muse, varscan2
- CHI3L1 | c.223A>T p.T75S | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55139388; called by muse, mutect2
- CHRM3 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV55095666; called by muse, mutect2, varscan2
- CILP | c.1294T>C p.C432R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56026192; called by muse, mutect2, varscan2
- CLEC2D | c.428G>T p.W143L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51995004; called by muse, mutect2, varscan2
- CNOT11 | c.1277A>T p.H426L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56820601; called by muse, mutect2, varscan2
- COL9A3 | c.908C>A p.P303Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV59654328; called by muse, mutect2, varscan2
- DNA2 | c.515A>T p.N172I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV63063222; called by mutect2, varscan2
- DNAJC22 | c.993T>A p.S331R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as COSV67712524; called by muse, mutect2, varscan2
- EIF5B | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV56815212; called by muse, mutect2, varscan2
- EPO | c.159G>A p.T53= | Splice Region (SNP) | VAF 8/38 reads (21%) | catalogued as rs747340501, COSV53161196; called by muse, mutect2, varscan2
- EVA1C | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100291545, COSV55825564; called by muse, mutect2
- EXOC2 | c.2166A>T p.E722D | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.422); catalogued as COSV57868930; called by muse, mutect2, varscan2
- EXOC5 | c.1653G>T p.L551F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV61771625, COSV61772173; called by muse, mutect2
- FAM78B | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57979956; called by muse, mutect2, varscan2
- FBXO34 | c.1801A>G p.T601A | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs1295822709, COSV58255711; called by muse, mutect2, varscan2
- FCRL1 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63826341; called by muse, mutect2, varscan2
- FHOD3 | c.1636C>T p.P546S (on ENST00000359247 / NM_001281739.3; = p.P563S on NM_025135.5) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.057); catalogued as COSV57180793; called by muse, mutect2, varscan2
- FOXI1 | c.1010G>T p.W337L | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.749); catalogued as COSV60389297; called by muse, mutect2, varscan2
- GID8 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99824090; called by muse, mutect2
- GNAL | c.81G>C p.K27N | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV52330801; called by muse, mutect2
- GOLGA3 | c.1834C>A p.H612N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV52637471; called by muse, mutect2, varscan2
- GPR162 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1231088025, COSV50590523; called by muse, mutect2
- HIF3A | c.1853C>A p.P618Q (on ENST00000377670 / NM_152795.4; = p.P549Q on NM_022462.4) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV52203617; called by muse, mutect2, varscan2
- HLA-G | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV64406297; called by muse, mutect2, varscan2
- HMBS | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as CM104056, COSV53829425; called by muse, mutect2, varscan2
- HOMER2 | c.661G>C p.E221Q (on ENST00000304231 / NM_199330.3; = p.E210Q on NM_004839.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58485815, COSV58487272; called by muse, mutect2, varscan2
- HOXA10 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52230227; called by muse, mutect2
- HSPA13 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as COSV53465840; called by muse, mutect2, varscan2
- IFI44L | c.479-1G>T p.X160_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100654975; called by muse, mutect2, varscan2
- IFI44L | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100654976; called by muse, mutect2, varscan2
- IFNA16 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV66510405; called by muse, mutect2, varscan2
- IGSF10 | c.3026G>C p.R1009P | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV104390288, COSV56788653; called by muse, mutect2, varscan2
- IGSF3 | c.1148A>C p.K383T | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59594855; called by muse, varscan2
- IL9R | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99729694; called by muse, mutect2
- IPMK | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64244098; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1487G>A p.R496K (on ENST00000485419 / NM_001197113.1; = p.R420K on NM_014575.3) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.913); catalogued as COSV61851186; called by muse, mutect2, varscan2
- KCNH5 | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs1263654608, COSV59763017, COSV59768313; called by muse, mutect2, varscan2
- KLHL10 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 83/199 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1555620330, COSV53174076; called by muse, mutect2, varscan2
- KLK13 | c.267C>A p.H89Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs138178458, COSV50067365; called by muse, mutect2, varscan2
- LRP1B | c.4192G>A p.D1398N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1375605745, COSV101256363; called by muse, mutect2, varscan2
- LRP1B | c.4191G>T p.W1397C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101256364; called by muse, mutect2, varscan2
- LRRC32 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as rs945861991, COSV52634244; called by muse, mutect2, varscan2
- LRRC4B | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.385); catalogued as COSV65350394; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65443043; called by muse, mutect2
- MCCC2 | c.1487A>G p.Q496R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV60155557; called by muse, mutect2, varscan2
- MCOLN3 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV62015097; called by muse, mutect2, varscan2
- MN1 | c.3514G>T p.D1172Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56560171; called by muse, mutect2, varscan2
- MROH7 | c.2914G>C p.E972Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV59875170; called by muse, mutect2, varscan2
- MTG2 | c.29G>T p.R10I | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.088); catalogued as COSV63694294; called by muse, mutect2
- MXRA5 | c.5894G>C p.G1965A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54242754; called by muse, mutect2, varscan2
- MYPN | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs927839092, COSV62736115, COSV62740210; called by muse, mutect2
- MYSM1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs773237401, COSV71763162, COSV71763199; called by mutect2, varscan2
- NCAN | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV53054625, COSV99388111; called by muse, mutect2, varscan2
- NCAPH2 | c.628A>T p.M210L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV55370566; called by muse, mutect2, varscan2
- NCOA2 | c.806G>A p.S269N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV71764439; called by muse, mutect2, varscan2
- NOS1 | c.2941G>T p.E981* | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | catalogued as COSV57613811, COSV57617010; called by muse, mutect2, varscan2
- NSD1 | c.1618G>T p.G540W | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV61779871; called by muse, mutect2, varscan2
- NXF1 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.403); catalogued as COSV53675436; called by muse, mutect2, varscan2
- OR8D2 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs776771740, COSV62488310; called by muse, mutect2, varscan2
- OR9G4 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs199908718, COSV57249224; called by muse, mutect2, varscan2
- PANK3 | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as rs1226426121, COSV53324307; called by muse, mutect2, varscan2
- PAPSS2 | c.805A>C p.K269Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as COSV63264345; called by muse, mutect2, varscan2
- PCDH10 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52099259, COSV52100781; called by muse, mutect2, varscan2
- PCDH11X | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53486874; called by muse, mutect2, varscan2
- PCDHA4 | c.2056G>C p.A686P | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as COSV100793379, COSV63543942; called by muse, mutect2, varscan2
- PCDHB15 | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1307378623, COSV51151419; called by muse, mutect2, varscan2
- PCDHB5 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50659143; called by muse, mutect2, varscan2
- PPARGC1A | c.2111A>T p.E704V | Missense Mutation (SNP) | VAF 70/100 reads (70%) | SIFT tolerated (1); PolyPhen possibly damaging (0.729); catalogued as COSV53530614; called by muse, mutect2, varscan2
- PRKD2 | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52188305; called by muse, mutect2, varscan2
- PRKDC | c.4142G>T p.S1381I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV100040801, COSV58058423; called by muse, mutect2, varscan2
- PROX1 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV54781379; called by muse, mutect2, varscan2
- RAPGEF2 | c.3080G>T p.R1027M | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV52431197; called by muse, mutect2, varscan2
- RETREG1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV60450518; called by muse, mutect2, varscan2
- ROR1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV64290139; called by muse, mutect2, varscan2
- RPGRIP1 | c.1467G>A p.E489= | Splice Region (SNP) | VAF 6/49 reads (12%) | catalogued as COSV52847342; called by muse, mutect2
- RTL5 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1462670346, COSV65454192; called by muse, mutect2, varscan2
- SAMD4A | c.1170G>T p.L390F | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51884862; called by muse, mutect2
- SETBP1 | c.2247del p.R750Gfs*34 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as COSV56313066; called by mutect2, pindel, varscan2
- SHROOM3 | c.4757C>T p.P1586L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56034674; called by muse, mutect2, varscan2
- SIGLEC14 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs758347134, COSV55778609; called by muse, mutect2, varscan2
- SLC25A32 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); catalogued as COSV52568445; called by muse, mutect2, varscan2
- SLCO6A1 | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.063); catalogued as COSV65812828, COSV65813556; called by muse, mutect2, varscan2
- SLIT2 | c.4445G>T p.C1482F | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56583552; called by muse, mutect2, varscan2
- SMG1 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs765183023, COSV67173411; called by muse, mutect2, varscan2
- STRN3 | c.2101G>A p.E701K (on ENST00000357479 / NM_001083893.2; = p.E617K on NM_014574.4) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62580891; called by muse, mutect2
- STYXL2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 24/548 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54807728; called by muse, mutect2
- SUCO | c.1569A>T p.G523= | Splice Region (SNP) | VAF 115/261 reads (44%) | catalogued as COSV55268415; called by muse, mutect2, varscan2
- SYNGAP1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 107/301 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs765011916, COSV53383927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACC2 | c.8790A>C p.E2930D (on ENST00000334433; = p.E1008D on NM_006997.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53285679; called by muse, mutect2, varscan2
- TAS2R16 | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs755510148, COSV50797989, COSV50798071; called by muse, mutect2, varscan2
- TBCC | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV55131377; called by muse, mutect2
- TEX2 | c.3374A>T p.D1125V (on ENST00000583097 / NM_001288733.2; = p.D1132V on NM_018469.5) | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as COSV99367067; called by muse, mutect2
- TEX2 | c.3373G>T p.D1125Y (on ENST00000583097 / NM_001288733.2; = p.D1132Y on NM_018469.5) | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV51986508; called by muse, mutect2
- THSD7A | c.2789G>A p.R930H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776573414, COSV70268654; called by muse, mutect2, varscan2
- THY1 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV52454875; called by muse, mutect2, varscan2
- TP53 | c.104del p.L35Cfs*9 | Frame Shift Del (DEL) | VAF 57/171 reads (33%) | catalogued as COSV52728232; called by mutect2, pindel, varscan2
- TRDMT1 | c.252-1G>C p.X84_splice | Splice Site (SNP) | VAF 25/89 reads (28%) | catalogued as COSV58320146; called by muse, mutect2, varscan2
- UQCRFS1 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59185172; called by muse, mutect2, varscan2
- XKR5 | c.416A>T p.D139V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs939700493, COSV68398576; called by muse, mutect2, varscan2
- ZBTB34 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as COSV59860388; called by muse, mutect2, varscan2
- ZFYVE1 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59611973; called by muse, mutect2, varscan2
- ZIM2 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV55640562; called by muse, mutect2, varscan2
- ZNF131 | c.1726G>T p.E576* (on ENST00000509156 / NM_001330707.2; = p.E542* on NM_003432.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV61003514; called by muse, mutect2, varscan2
- ZNF761 | c.2157G>T p.K719N | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61888935; called by muse, mutect2, varscan2
- AC136428.1 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.103); called by mutect2, varscan2
- CA2 | c.71_83del p.K24Sfs*17 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | called by pindel, varscan2
- CRYBG2 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); called by muse, mutect2
- DSEL | c.1257del p.H420Tfs*39 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- JTB | c.18_33del p.P8Afs*13 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- LTN1 | c.1848del p.L617Ffs*33 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- MARK1 | c.638dup p.L213Ffs*22 | Frame Shift Ins (INS) | VAF 35/76 reads (46%) | called by mutect2, pindel, varscan2
- MGRN1 | c.994_996del p.K332del | In Frame Del (DEL) | VAF 11/48 reads (23%) | called by pindel, varscan2
- PRPF4B | c.924del p.S309Pfs*63 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- PRRC2B | c.4701del p.K1568Rfs*49 | Frame Shift Del (DEL) | VAF 31/119 reads (26%) | called by mutect2, pindel, varscan2
- SEPHS1 | c.799_819del p.T267_G273del | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- SGO2 | c.699del p.R234Efs*15 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- ABCA1 | c.4752G>A p.L1584= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as COSV66068507; called by muse, mutect2
- ADGRE2 | c.1053G>A p.G351= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV59695011; called by muse, mutect2, varscan2
- AK7 | c.2121T>C p.P707= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV50876388; called by muse, mutect2, varscan2
- AMPH | c.1713C>T p.D571= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1447440426, COSV57743553; called by muse, mutect2, varscan2
- BAZ2A | c.2253G>A p.K751= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV51640205; called by muse, mutect2, varscan2
- BTBD11 | c.1053G>A p.L351= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV55030617; called by muse, mutect2
- CCDC116 | c.1839C>A p.V613= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV53041587; called by muse, mutect2
- CFHR1 | c.660T>C p.T220= | Silent (SNP) | VAF 79/209 reads (38%) | catalogued as COSV57628111; called by muse, mutect2
- CISH | c.633G>T p.V211= (on ENST00000348721 / NM_145071.4; = p.V228= on NM_013324.6) | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as COSV62295199; called by muse, mutect2, varscan2
- CYB561A3 | c.46C>T p.L16= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV53652860; called by muse, mutect2
- DIP2A | c.300C>T p.A100= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs139510335, COSV59472795; called by muse, mutect2
- DNAH3 | c.11640C>T p.L3880= | Silent (SNP) | VAF 183/489 reads (37%) | catalogued as COSV54536252; called by muse, mutect2, varscan2
- DPY19L1 | c.1182G>A p.E394= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs750529586, COSV60583221; called by muse, mutect2, varscan2
- GFRA3 | c.279C>T p.L93= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV51229674; called by muse, mutect2, varscan2
- GPR12 | c.276G>T p.L92= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV67344631; called by muse, mutect2, varscan2
- GPR174 | c.540C>G p.A180= | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as COSV52131835, COSV52133433; called by muse, mutect2, varscan2
- HCN1 | c.2091C>T p.C697= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV57524565; called by muse, mutect2, varscan2
- HOXC9 | c.165C>T p.F55= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1407570013, COSV57716319; called by muse, mutect2
- HRH2 | c.126C>A p.A42= | Silent (SNP) | VAF 67/239 reads (28%) | catalogued as COSV51575182; called by muse, mutect2, varscan2
- ITGA10 | c.813G>T p.L271= | Silent (SNP) | VAF 15/182 reads (8%) | catalogued as COSV65198269; called by muse, mutect2
- LMO2 | c.96C>T p.G32= (on ENST00000395833 / NM_001142315.2; = p.G101= on NM_005574.4) | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV57646832; called by muse, mutect2
- MPPED2 | c.849A>C p.P283= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs781117761, COSV63899874; called by muse, mutect2, varscan2
- MYCBP2 | c.783C>T p.I261= (on ENST00000357337; = p.I299= on NM_015057.5) | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV62029567; called by muse, mutect2, varscan2
- NCAN | c.2244G>A p.T748= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs749493759, COSV53054644; called by muse, mutect2
- OPTC | c.846C>A p.T282= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV65867925, COSV65868220; called by muse, mutect2, varscan2
- OR2T6 | c.288C>A p.A96= | Silent (SNP) | VAF 68/109 reads (62%) | catalogued as COSV63216669; called by muse, mutect2, varscan2
- PIKFYVE | c.2475G>T p.L825= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV52245377; called by muse, mutect2, varscan2
- PPP1R13B | c.1923T>A p.P641= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV52453977; called by muse, mutect2, varscan2
- RNASEL | c.1524C>A p.I508= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV62377435; called by muse, mutect2, varscan2
- RTTN | c.3559C>T p.L1187= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV55348459; called by muse, mutect2, varscan2
- SALL1 | c.3735G>A p.L1245= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV51761140; called by muse, mutect2, varscan2
- TPX2 | c.48C>T p.F16= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV55920980; called by muse, mutect2, varscan2
- USP5 | c.672C>T p.F224= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as rs201246451, COSV57537597; called by muse, mutect2
- FBXW7 | c.502-2365T>C | Intron (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99656642; called by muse, mutect2, varscan2
- TTN | c.10360+1100G>T | Intron (SNP) | VAF 20/118 reads (17%) | catalogued as COSV60198723; called by muse, mutect2, varscan2
- TUFT1 | c.60+5410G>A | Intron (SNP) | VAF 14/53 reads (26%) | catalogued as COSV61949659; called by muse, mutect2, varscan2
